Gene-level copy-number profile of tumor specimen TCGA-39-5019-01A from TCGA case TCGA-39-5019, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 70.5 years (25,756 days).
Specimen TCGA-39-5019-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.8b69fa57-ebd9-4b30-badf-6ee327dae733.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-39-5019-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f0151184-f1e8-4566-8c29-bc8f8e0c0efa

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 311; copy number 1: 576; copy number 2: 7,807; copy number 3: 20,065; copy number 4: 10,027; copy number 5: 8,245; copy number 6: 7,268; copy number 7: 1,781; copy number 8: 2,615; copy number 9: 53; copy number 10: 339; copy number 11: 36; copy number 15: 6; copy number 16: 3; copy number 17: 51; copy number 18: 115; copy number 19: 48; copy number 20: 13; copy number 23: 29; copy number 25: 148; copy number 26: 7; copy number 27: 73; copy number 28: 2; copy number 29: 108; copy number 30: 16; copy number 32: 22; copy number 34: 2; copy number 36: 47.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-39-5019-01A-01D-1816-01): tumor purity 0.55, ploidy 1.31, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 303 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:7,796,500–7,961,224, 3 genes (within-gene range 0–3): DMAC1, AL135923.2, AL135923.1.
- chr9:8,700,595–8,864,772, 4 genes: AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1.
- chr9:13,927,971–15,307,360, 25 genes (within-gene range 0–5): LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B.
- chr9:16,409,503–16,870,843, 1 gene (within-gene range 0–5): BNC2.
- chr9:16,625,676–17,114,122, 8 genes: AL450003.1, BNC2-AS1, LSM1P1, AL162725.2, AL358117.1, RN7SL720P, RPS29P33, AL162725.1.
- chr9:19,507,452–26,118,408, 97 genes (within-gene range 0–3) (broad region; genes not listed).
- chr9:27,524,314–30,800,746, 23 genes: IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36.
- chr9:37,915,898–43,045,120, 142 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5,514 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:94,506,766–99,799,226, 73 genes, copy number 27 (within-gene range 6–27) (broad region; genes not listed).
- chr3:103,159,960–104,503,266, 7 genes, copy number 7–34: RNU1-43P, NDUFA4P2, MIR548AB, AC046144.1, TUBBP11, RAP1BP2, AC091804.1.
- chr3:114,314,500–115,147,288, 1 gene, copy number 8 (within-gene range 2–8): ZBTB20.
- chr3:114,684,580–115,721,490, 11 genes, copy number 8: ZBTB20-AS2, MIR4796, ZBTB20-AS3, YBX1P3, ZBTB20-AS4, AC026341.1, EIF4E2P2, AC026341.2, AC026341.3, GAP43, AC092468.1.
- chr3:115,837,870–115,838,159, 1 gene, copy number 8: RN7SL815P.
- chr3:129,647,792–131,527,179, 46 genes, copy number 9 (within-gene range 3–11): TMCC1, RNY3P13, U6, AC083799.1, TMCC1-AS1, AC083906.3, TRH, AC083906.1, AC083906.5, AC083906.2, OR7E129P, OR7E21P, AC083906.4, ALG1L2, LINC02014, FAM86HP, LINC02021, ENPP7P3, AC130888.1, SNRPCP8, COL6A4P2, AC093004.1, COL6A5, COL6A6, PIK3R4, RN7SKP212, AC097105.1, GSTO3P, ATP2C1, AC055733.4, AC055733.2, Y_RNA, AC055733.1, AC055733.3, ASTE1, NEK11, AC116424.1, RNU6-726P, AC010210.1, NUDT16P1, NUDT16, AC107027.3, MRPL3, SNORA58, AC107027.1, BCL2L12P1.
- chr3:131,537,571–131,537,685, 1 gene, copy number 9: AC107027.2.
- chr3:143,265,222–143,848,485, 1 gene, copy number 8 (within-gene range 6–8): SLC9A9.
- chr3:143,342,246–159,897,366, 258 genes, copy number 8–28 (within-gene range 6–28) (broad region; genes not listed).
- chr3:163,026,396–174,286,644, 141 genes, copy number 17–29 (within-gene range 4–29) (broad region; genes not listed).
- chr3:174,438,573–175,810,548, 1 gene, copy number 30 (within-gene range 4–30): NAALADL2.
- chr3:175,059,361–191,591,097, 309 genes, copy number 7–36 (within-gene range 6–36) (broad region; genes not listed).
- chr3:197,042,560–198,222,513, 36 genes, copy number 8: DLG1, MIR4797, DLG1-AS1, AL121981.1, AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.4, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1, FAM157A.
- chr4:43,972,921–45,480,136, 16 genes, copy number 7 (within-gene range 2–7): AC114757.1, LINC02475, KCTD8, AC093852.1, YIPF7, GUF1, GNPDA2, AC096586.2, AC096586.1, AC093755.1, PRDX4P1, AC108467.2, AC108467.1, THAP12P9, AC108043.1, RNU6-931P.
- chr4:67,701,209–68,080,952, 1 gene, copy number 10 (within-gene range 6–10): UBA6-AS1.
- chr4:67,737,118–70,337,116, 86 genes, copy number 10 (broad region; genes not listed).
- chr7:63,113,635–159,233,377, 1,931 genes, copy number 8 (broad region; genes not listed).
- chr8:28,494,205–42,555,195, 265 genes, copy number 10–20 (within-gene range 1–20) (broad region; genes not listed).
- chr8:126,325,454–128,564,679, 36 genes, copy number 11: AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr9:8,314,246–10,612,723, 1 gene, copy number 7 (within-gene range 0–7): PTPRD.
- chr9:8,936,079–13,836,571, 32 genes, copy number 7 (within-gene range 0–7): AL596451.1, RPS26P3, RN7SL5P, AL513422.1, AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL355672.1, AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1.
- chr9:17,134,982–17,503,923, 1 gene, copy number 16 (within-gene range 0–16): CNTLN.
- chr14:24,290,598–25,432,234, 27 genes, copy number 7 (within-gene range 3–7): DHRS1, NOP9, CIDEB, LTB4R2, LTB4R, ADCY4, AL096870.1, RIPK3, U6, NFATC4, NYNRIN, CBLN3, KHNYN, SDR39U1, AL132800.1, CMA1, CTSG, AL136018.1, GZMH, GZMB, STXBP6, AL161663.2, AL161663.1, LINC02286, HMGN2P6, OR7K1P, AL079352.1.
- chr14:25,806,648–25,822,741, 2 genes, copy number 7: AL359396.1, AL359396.2.
- chr14:26,443,090–43,541,826, 239 genes, copy number 7 (broad region; genes not listed).
- chr17:52,390,515–83,095,122, 916 genes, copy number 7 (broad region; genes not listed).
- chr19:11,505,929–21,196,053, 542 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr22:33,162,226–33,922,841, 1 gene, copy number 8 (within-gene range 5–8): LARGE1.
- chr22:33,704,786–50,801,309, 532 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 576. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
